Somatic mutation profile of tumor specimen TCGA-95-A4VN-01A (aliquot TCGA-95-A4VN-01A-11D-A25L-08) from TCGA case TCGA-95-A4VN, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.8 years (22,927 days).
Specimen TCGA-95-A4VN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb79aaa7-4bdb-4a97-ab9a-5f8703101bc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-A4VN-10A (Blood Derived Normal), aliquot TCGA-95-A4VN-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1b5c106-1005-4566-9333-73a15d148823

The open-access MAF lists 492 somatic variants for this specimen: 369 protein-altering or splice-affecting, 103 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 103, Nonsense Mutation 32, Intron 9, Frame Shift Del 6, Splice Site 5, RNA 4, 5'Flank 4, Frame Shift Ins 3, Splice Region 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs754903810, COSV58650474; called by muse, mutect2, varscan2
- ACAP1 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV50134798, COSV99341927; called by muse, mutect2, varscan2
- ACOT12 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1037776606, COSV100297136; called by muse, mutect2
- ACOT9 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100321430, COSV60538619; called by muse, mutect2
- ACVR1C | c.270T>A p.D90E | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99695000; called by muse, mutect2, varscan2
- ADGRA1 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs1370877712, COSV101658621, COSV74142919; called by muse, mutect2, varscan2
- ALCAM | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as rs765175016, COSV100065525; called by muse, mutect2, varscan2
- AMY2A | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 39/583 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340669; called by muse, mutect2
- ANGPT4 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101124857; called by muse, mutect2
- ANO4 | c.1405C>T p.R469* (on ENST00000392977 / NM_001286615.2; = p.R434* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 15/205 reads (7%) | catalogued as rs775993661, COSV100151219; called by muse, mutect2
- APOB | c.6040C>A p.L2014M | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99267467; called by muse, mutect2, varscan2
- APOB | c.4862C>A p.S1621Y | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51940164, COSV99267469; called by muse, mutect2, varscan2
- APOC2 | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV52991090, COSV99377030; called by muse, mutect2, varscan2
- AQR | c.3030A>T p.E1010D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50031167; called by muse, mutect2, varscan2
- ARC | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs1040102351, COSV100751773; called by muse, mutect2, varscan2
- ARHGEF37 | c.34A>T p.R12W | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV100382286; called by muse, mutect2, varscan2
- ARID4B | c.3904G>T p.A1302S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99936194, COSV99936239; called by muse, mutect2, varscan2
- ARMC12 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99849579; called by muse, mutect2, varscan2
- ARMCX5 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99863537; called by muse, mutect2
- ASIC5 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV72232926; called by muse, mutect2
- ASPA | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | catalogued as COSV52152047, COSV99279381; called by muse, mutect2
- ASTN1 | c.3790G>C p.D1264H | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100707618; called by muse, mutect2
- ATCAY | c.762C>A p.Y254* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100008969; called by muse, mutect2, varscan2
- ATP8A2 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99683826; called by muse, mutect2, varscan2
- AUTS2 | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100719414; called by muse, mutect2, varscan2
- BCOR | c.1894G>T p.G632C | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100653958, COSV60706701; called by muse, mutect2, varscan2
- BCR | c.1664A>T p.E555V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100006980; called by muse, mutect2, varscan2
- BPI | c.937G>T p.D313Y (on ENST00000262865; = p.D309Y on NM_001725.3) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99480914; called by muse, mutect2
- BRIP1 | c.3659A>T p.E1220V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV99370867; called by muse, mutect2, varscan2
- BRWD3 | c.2489T>C p.V830A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100956435; called by muse, mutect2
- C1QC | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs139780188, COSV101009538; called by muse, mutect2, varscan2
- CACNA1F | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs781815787, COSV100545305; called by muse, mutect2
- CALN1 | c.226G>T p.E76* (on ENST00000329008 / NM_001017440.3; = p.E118* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100208893; called by muse, mutect2, varscan2
- CAPN13 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99700964; called by muse, mutect2, varscan2
- CARMIL1 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV100278697; called by muse, mutect2, varscan2
- CCDC173 | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760546331, COSV101352358, COSV101352367; called by muse, mutect2, varscan2
- CCDC7 | c.1242A>T p.Q414H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV99511850; called by muse, mutect2, varscan2
- CCL25 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV99495240; called by muse, mutect2
- CCSER1 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100395431; called by muse, mutect2, varscan2
- CCT5 | c.1360G>C p.A454P | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54723982, COSV99725563; called by muse, mutect2
- CCT8L2 | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs187222873; called by muse, mutect2, varscan2
- CD101 | c.2311A>T p.S771C | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99870130; called by muse, mutect2, varscan2
- CD226 | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99711468; called by muse, mutect2
- CD99L2 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); catalogued as rs782475939, COSV100692496; called by muse, mutect2
- CDH7 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as COSV99064582; called by muse, mutect2, varscan2
- CDHR1 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs142917517; called by muse, mutect2, varscan2
- CDHR2 | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs749604911, COSV99992108; called by muse, varscan2
- CFP | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV99901641; called by muse, mutect2, varscan2
- CHD8 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV101303201; called by muse, mutect2
- CHUK | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.782); catalogued as COSV100957268; called by muse, mutect2, varscan2
- CMTR2 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100579321; called by muse, mutect2, varscan2
- COL17A1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100793321; called by muse, mutect2, varscan2
- CPN2 | c.1049C>A p.T350K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs920257407, COSV100103253; called by muse, mutect2, varscan2
- CR1 | c.891T>A p.C297* (on ENST00000367051; = p.C747* on NM_000651.6) | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100887993; called by mutect2, varscan2
- CRACD | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs370635943; called by muse, mutect2, varscan2
- CROT | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV100519659; called by muse, mutect2
- CSMD3 | c.4102G>T p.D1368Y (on ENST00000297405 / NM_001363185.1; = p.D1264Y on NM_052900.3) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99845446; called by muse, mutect2, varscan2
- CSTF1 | c.752G>T p.C251F | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99410326; called by muse, mutect2, varscan2
- CTDP1 | c.2113G>T p.V705L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs372703325, COSV99311037; called by muse, mutect2, varscan2
- CTR9 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100797496; called by muse, mutect2, varscan2
- CUBN | c.1901C>T p.T634I | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1387513392, COSV100913406; called by muse, mutect2, varscan2
- CYCS | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99995092; called by muse, mutect2, varscan2
- DAOA | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.399); catalogued as COSV61602376; called by muse, mutect2, varscan2
- DCAF12L1 | c.579C>A p.H193Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948334; called by muse, mutect2, varscan2
- DCAF12L1 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs1306207998, COSV100948428, COSV64421531; called by muse, mutect2, varscan2
- DIP2C | c.2900G>T p.R967L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99793461; called by muse, mutect2, varscan2
- DISP3 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99609793; called by muse, mutect2, varscan2
- DLG2 | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV99718947; called by muse, mutect2, varscan2
- DNMT3B | c.1981A>T p.R661W | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143543; called by muse, mutect2, varscan2
- DOCK10 | c.5440T>A p.Y1814N | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99291256; called by muse, mutect2, varscan2
- DRD4 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99448850; called by muse, mutect2
- DUSP22 | c.138+1G>T p.X46_splice | Splice Site (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100740038; called by muse, mutect2
- DYNC2H1 | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100519544; called by muse, mutect2, varscan2
- ELF1 | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99523292; called by muse, mutect2
- EN1 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.327); catalogued as COSV54630863, COSV99727391; called by muse, mutect2
- EPHA5 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56630335; called by muse, mutect2, varscan2
- ERICH3 | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV100445441; called by muse, mutect2, varscan2
- FA2H | c.959T>G p.F320C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99547907; called by muse, mutect2, varscan2
- FAM114A2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100697781; called by muse, mutect2, varscan2
- FAM227B | c.157A>C p.T53P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as rs1045435212, COSV100175519; called by muse, mutect2
- FAM47A | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1555968141, COSV100650036; called by muse, mutect2, varscan2
- FAT1 | c.12362del p.G4121Efs*85 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as COSV71673701; called by mutect2, pindel, varscan2
- FBN2 | c.4422C>G p.C1474W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52500874, COSV99330174; called by muse, mutect2, varscan2
- FBN3 | c.6473C>A p.P2158H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99561693; called by muse, mutect2, varscan2
- FCN2 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52475726, COSV52479112, COSV99391425; called by muse, mutect2, varscan2
- FCRL5 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.089); catalogued as COSV62518470; called by muse, mutect2, varscan2
- FCRLA | c.953C>A p.P318Q (on ENST00000367959; = p.P295Q on NM_032738.4) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV52685803, COSV99376552; called by muse, mutect2, varscan2
- FEM1C | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99174416; called by muse, mutect2, varscan2
- FER | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99813783; called by muse, mutect2, varscan2
- FERD3L | c.451T>A p.S151T | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV51764002, COSV99285069; called by muse, mutect2
- FGF7 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99983597; called by muse, mutect2, varscan2
- FGFR4 | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99450448; called by muse, mutect2, varscan2
- FGG | c.124-1G>T p.X42_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100272033; called by mutect2, varscan2
- FLG | c.10462C>A p.Q3488K | Missense Mutation (SNP) | VAF 180/686 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.689); catalogued as rs747694465, COSV100911361, COSV64235923; called by muse, mutect2, varscan2
- FMR1NB | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.375); catalogued as rs782135236, COSV65072393; called by muse, mutect2, varscan2
- FNDC3B | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.065); catalogued as COSV100394786; called by muse, mutect2, varscan2
- FRY | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV100969822; called by muse, mutect2, varscan2
- FRY | c.8017C>A p.Q2673K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as COSV66575991; called by muse, mutect2
- FSTL5 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV60195512; called by muse, mutect2, varscan2
- G6PC | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as CM000386, COSV99520949; called by muse, mutect2, varscan2
- GABRB2 | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV99196512; called by muse, mutect2, varscan2
- GABRD | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66081028; called by muse, mutect2
- GABRG3 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100409470; called by muse, mutect2, varscan2
- GAD2 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.051); catalogued as COSV99393911; called by muse, mutect2, varscan2
- GAS2L3 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 43/209 reads (21%) | catalogued as COSV99903070; called by muse, mutect2, varscan2
- GDF9 | c.1257T>A p.C419* | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as COSV99737496; called by muse, mutect2, varscan2
- GFRAL | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs1326419208, COSV100475777; called by muse, mutect2, varscan2
- GIMAP6 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as COSV100188367, COSV61032997; called by muse, mutect2
- GLA | c.786G>T p.W262C | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM051527, COSV99516561; called by muse, mutect2
- GLDC | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394507; called by muse, mutect2, varscan2
- GLI3 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101230016; called by muse, mutect2
- GOLGA3 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV99212505; called by muse, mutect2
- GPAT2 | c.1614C>A p.H538Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV100853347; called by muse, mutect2, varscan2
- GPATCH1 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99404291; called by muse, mutect2, varscan2
- GPR37 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 12/127 reads (9%) | catalogued as COSV100391121; called by muse, mutect2
- GRB10 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100240971; called by muse, mutect2
- GRIP1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 51/269 reads (19%) | catalogued as COSV99670722; called by muse, mutect2, varscan2
- GRM5 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.217); catalogued as COSV100554145; called by mutect2, varscan2
- GUCY1B1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV100025851; called by muse, mutect2, varscan2
- GZMH | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV99361956, COSV99362033; called by muse, mutect2
- HPS5 | c.600T>A p.C200* (on ENST00000349215 / NM_181507.2; = p.C86* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100834473; called by muse, mutect2, varscan2
- HSPG2 | c.10691C>T p.T3564I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV101013547; called by muse, mutect2, varscan2
- HUWE1 | c.6401T>A p.L2134Q | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99473926; called by muse, mutect2
- IGSF1 | c.1685T>A p.M562K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100812282; called by muse, mutect2, varscan2
- IKBKG | c.50G>C p.S17T | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99682467; called by muse, mutect2
- INPP5D | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100856902, COSV64040613; called by muse, mutect2, varscan2
- INTS11 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761966262, COSV60089650; called by muse, mutect2, varscan2
- ITGA4 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99276750; called by muse, mutect2, varscan2
- ITGAX | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99191993; called by muse, mutect2
- ITGAX | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs778229735, COSV99191994; called by muse, mutect2, varscan2
- ITGB1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171947; called by muse, mutect2
- ITPRID1 | c.3125T>A p.V1042D | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV100087339; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1225G>C p.V409L (on ENST00000439118 / NM_001008949.3; = p.V417L on NM_178495.6) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV100742236; called by muse, mutect2, varscan2
- JAKMIP3 | c.1135A>T p.I379L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100059805; called by muse, mutect2, varscan2
- KBTBD12 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100675506; called by muse, mutect2, varscan2
- KBTBD3 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.358); catalogued as COSV101595719; called by muse, mutect2, varscan2
- KCNS2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1308589032, COSV54638374; called by muse, mutect2, varscan2
- KCTD18 | c.304A>G p.S102G | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV100728941; called by muse, mutect2, varscan2
- KIAA0319 | c.2611G>T p.V871L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1271996180, COSV100985766; called by muse, mutect2, varscan2
- KIAA0930 | c.1003G>T p.D335Y (on ENST00000336156 / NM_001009880.2; = p.D340Y on NM_015264.2) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99326012; called by muse, mutect2
- KIAA0930 | c.1002G>T p.E334D (on ENST00000336156 / NM_001009880.2; = p.E339D on NM_015264.2) | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99326013; called by muse, mutect2
- KIF19 | c.2609G>C p.R870P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV100739160; called by muse, mutect2
- KIF3C | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs760016402, COSV99267844; called by muse, mutect2, varscan2
- KLHL5 | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV99785766; called by muse, mutect2
- KMT2A | c.11626G>A p.D3876N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV63293579; called by muse, mutect2
- KRT38 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs1163846955, COSV99878359; called by muse, mutect2, varscan2
- KRTAP20-1 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 6/131 reads (5%) | PolyPhen benign (0.036); catalogued as rs1263648090, COSV100228829, COSV58168394; called by muse, mutect2
- KRTAP5-10 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV100924161; called by muse, mutect2, varscan2
- LIFR | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV99665276; called by muse, mutect2, varscan2
- LILRB3 | c.1513C>A p.P505T (on ENST00000346401; = p.P493T on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as COSV54444657, COSV99558359; called by muse, mutect2, varscan2
- LILRB4 | c.1310C>G p.P437R (on ENST00000391733 / NM_001278428.3; = p.P436R on NM_001278426.3) | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV54404704, COSV99554071; called by muse, mutect2
- LIPJ | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100905924; called by muse, mutect2, varscan2
- LMBR1L | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99918952; called by muse, mutect2
- LOX | c.1132-2A>T p.X378_splice | Splice Site (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99140688; called by muse, mutect2, varscan2
- LRRC47 | c.618G>T p.T206= | Splice Region (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100989358; called by muse, mutect2, varscan2
- LRRC4C | c.1186C>A p.H396N | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs970993511, COSV99539417; called by muse, mutect2, varscan2
- LRRIQ1 | c.3899A>T p.E1300V | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV101280689; called by muse, mutect2
- LRRN2 | c.1816A>T p.T606S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV100912933; called by muse, varscan2
- LRRTM1 | c.1361C>A p.P454Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54448715; called by muse, mutect2, varscan2
- LRRTM4 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV101297705; called by muse, mutect2
- LRRTM4 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.423); catalogued as COSV101297709; called by muse, mutect2, varscan2
- LVRN | c.2739G>T p.W913C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455191468, COSV100773648; called by muse, mutect2
- MAEA | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV53261897, COSV99295667; called by muse, mutect2, varscan2
- MAGEC3 | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.519); catalogued as COSV100025988, COSV104403532; called by muse, mutect2, varscan2
- MAGED1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.985); catalogued as COSV100431777; called by muse, mutect2
- MAN2A1 | c.2729T>A p.L910* | Nonsense Mutation (SNP) | VAF 28/238 reads (12%) | catalogued as COSV99811681, COSV99811784; called by muse, mutect2, varscan2
- MBL2 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 78/501 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.406); catalogued as COSV100906393; called by muse, mutect2, varscan2
- MC5R | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100229151; called by muse, mutect2, varscan2
- MECP2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV100318448, COSV57658195; called by muse, mutect2, varscan2
- MED27 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.204); catalogued as rs760597063, COSV99406829; called by muse, mutect2
- MED31 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 11/134 reads (8%) | catalogued as COSV99854625; called by muse, mutect2
- MEOX2 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100012464; called by muse, mutect2, varscan2
- MFF | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs201993285, COSV100449391; called by muse, mutect2, varscan2
- MICU2 | c.1055G>T p.R352I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101212482; called by muse, mutect2
- MLXIPL | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100515515; called by muse, mutect2, varscan2
- MMP19 | c.1483T>A p.L495M | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV100491244; called by muse, mutect2, varscan2
- MMUT | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs766529896, COSV51272223; called by muse, mutect2, varscan2
- MOG | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100973107; called by muse, mutect2, varscan2
- MPPED2 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100813515; called by muse, mutect2
- MPPED2 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813516; called by muse, mutect2, varscan2
- MROH6 | c.1688G>T p.W563L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101295832; called by muse, mutect2, varscan2
- MUC16 | c.40565C>A p.T13522N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101110056; called by muse, mutect2
- MUC16 | c.31951G>C p.A10651P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.529); catalogued as COSV101198393, COSV101200948; called by muse, mutect2
- MUC17 | c.5311G>T p.A1771S | Missense Mutation (SNP) | VAF 186/780 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100074812; called by muse, mutect2, varscan2
- MXRA5 | c.4840C>A p.L1614I | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV99478875; called by muse, mutect2, varscan2
- MYH9 | c.3803G>T p.R1268L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV53391295, COSV99339704; called by muse, mutect2
- MYOC | c.215A>T p.H72L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99231687; called by muse, mutect2, varscan2
- MYOM2 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100038177, COSV100038228; called by muse, mutect2
- NAALADL1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100368222; called by muse, mutect2, varscan2
- NCAN | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs150327139; called by muse, mutect2, varscan2
- NCKAP1 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100720529; called by muse, mutect2
- NCOA6 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1225522868, COSV100750279; called by muse, mutect2, varscan2
- NKRF | c.1629G>T p.E543D | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1267208770, COSV100441844; called by muse, mutect2
- NLGN1 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849991; called by muse, mutect2, varscan2
- NLRP11 | c.2004-1G>T p.X668_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100789725, COSV100789798; called by muse, mutect2, varscan2
- NLRP3 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV100276544; called by muse, mutect2, varscan2
- NLRP8 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.931); catalogued as rs370475583; called by muse, mutect2, varscan2
- NOP14 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); catalogued as COSV100054523, COSV100054979; called by muse, mutect2, varscan2
- NRG3 | c.1834C>A p.Q612K (on ENST00000404547 / NM_001370084.1; = p.Q588K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100932519; called by muse, mutect2, varscan2
- NRXN3 | c.1404G>T p.M468I (on ENST00000335750 / NM_001330195.2; = p.M95I on NM_004796.6) | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV100204845, COSV59784430; called by muse, mutect2
- NRXN3 | c.2777G>T p.G926V (on ENST00000335750 / NM_001330195.2; = p.G553V on NM_004796.6) | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100208108; called by muse, mutect2
- OLFM1 | c.553G>T p.V185F (on ENST00000371793 / NM_001282611.2; = p.V167F on NM_014279.5) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as COSV99424216; called by muse, mutect2
- OPN5 | c.297G>C p.W99C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790010; called by muse, mutect2, varscan2
- OR10A2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV56300196; called by muse, mutect2
- OR10V1 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.021); catalogued as COSV100276218; called by muse, varscan2
- OR14J1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV101012837; called by muse, mutect2, varscan2
- OR1Q1 | c.769T>A p.W257R | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99939344; called by muse, mutect2
- OR2A12 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1476457578, COSV101283197; called by muse, mutect2, varscan2
- OR51G1 | c.699C>A p.H233Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100429383; called by muse, mutect2, varscan2
- OR5D18 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100450843, COSV61738281; called by muse, mutect2, varscan2
- OR5H14 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101454266; called by muse, mutect2, varscan2
- OR5L1 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 17/279 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV100450222, COSV61735185; called by muse, mutect2
- OR7D4 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100432852; called by muse, mutect2
- OR7E24 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV101509682; called by muse, mutect2, varscan2
- OS9 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV99233077; called by muse, mutect2
- OTOF | c.1499G>C p.R500P | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99718751; called by muse, mutect2, varscan2
- OTULINL | c.225-2A>T p.X75_splice | Splice Site (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99947334; called by muse, mutect2
- PALM2AKAP2 | c.1411C>A p.L471I (on ENST00000259318 / NM_001136562.3; = p.L702I on NM_007203.5) | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as COSV99395643; called by muse, mutect2, varscan2
- PCDH1 | c.2906A>T p.Y969F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746846; called by muse, mutect2, varscan2
- PCDH11X | c.2562G>T p.W854C | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014510; called by muse, mutect2, varscan2
- PCDH15 | c.1730G>T p.R577L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs753457449, COSV100226452, COSV57270179; called by muse, mutect2, varscan2
- PCDHA2 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs1461774717, COSV100974123; called by muse, mutect2, varscan2
- PCDHA9 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100970016; called by muse, varscan2
- PCDHB9 | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.413); catalogued as rs1428832290; called by muse, mutect2
- PCDHGA3 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV99545412; called by muse, mutect2, varscan2
- PCDHGC4 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV99341961; called by muse, mutect2, varscan2
- PDSS1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873621; called by muse, mutect2
- PGAM4 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100431521; called by muse, mutect2
- PGBD5 | c.775A>T p.S259C (on ENST00000525115; = p.S328C on NM_001258311.2) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100358838; called by muse, mutect2
- PIP4P2 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs751782382, COSV99575552; called by muse, mutect2, varscan2
- PLD1 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV100578732; called by muse, mutect2, varscan2
- POLA1 | c.3159G>T p.K1053N | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100985740; called by muse, mutect2
- POLI | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471233; called by muse, mutect2
- POLQ | c.4864G>T p.G1622W | Missense Mutation (SNP) | VAF 87/429 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as COSV99952820; called by muse, mutect2, varscan2
- POLR3B | c.1400del p.G467Vfs*33 | Frame Shift Del (DEL) | VAF 46/199 reads (23%) | catalogued as COSV57275885; called by mutect2, pindel, varscan2
- POM121L12 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.096); catalogued as COSV101374971; called by muse, mutect2, varscan2
- POMC | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV53034743, COSV53035983; called by muse, mutect2, varscan2
- POTEH | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs553502681, COSV58885531; called by muse, mutect2
- POU3F4 | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100937317; called by muse, mutect2, varscan2
- PRKACB | c.992A>C p.Y331S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100854102; called by muse, mutect2, varscan2
- PRLH | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51255559, COSV99382237; called by muse, mutect2, varscan2
- PROKR1 | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375695, COSV58137714; called by muse, mutect2, varscan2
- PROZ | c.1083C>A p.H361Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1243121593, COSV61440661; called by muse, mutect2
- PRPF6 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99412677; called by muse, mutect2
- PRTFDC1 | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 182/561 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100197134; called by muse, mutect2, varscan2
- PSG4 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99737705; called by muse, mutect2, varscan2
- PSG7 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101343322; called by muse, mutect2, varscan2
- PSG8 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100126556; called by muse, mutect2, varscan2
- PTCHD1 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as COSV101037965, COSV65061142, COSV65062604; called by muse, mutect2, varscan2
- PTPRB | c.5917C>A p.Q1973K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs758921610, COSV54260372; called by muse, mutect2, varscan2
- PTPRD | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100645924, COSV61970256; called by muse, mutect2, varscan2
- PTPRN2 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101235262; called by mutect2, varscan2
- PYGO2 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as COSV100868980; called by muse, mutect2, varscan2
- QSER1 | c.3572C>T p.P1191L (on ENST00000399302; = p.P1320L on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV101234957; called by muse, mutect2
- RAP1GAP | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs866407168, COSV51573957; called by muse, mutect2
- RETREG2 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as COSV56087353, COSV99811680; called by muse, mutect2, varscan2
- RFPL1 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV100585881; called by muse, mutect2, varscan2
- RHO | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99960766; called by muse, mutect2, varscan2
- RIMS2 | c.940G>A p.V314M (on ENST00000666250 / NM_001348490.2; = p.V122M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV99192595; called by muse, mutect2
- RP1L1 | c.5107G>T p.G1703W | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99059375; called by muse, mutect2
- RYR2 | c.14188G>T p.V4730F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV100772453; called by muse, mutect2, varscan2
- SAMSN1 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1403590253, COSV99582243; called by muse, mutect2, varscan2
- SEMA5B | c.1820C>A p.T607K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99533002; called by muse, mutect2, varscan2
- SEPTIN14 | c.652A>C p.N218H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.33); catalogued as COSV101193419; called by muse, mutect2, varscan2
- SERPINA11 | c.1138C>A p.Q380K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.055); catalogued as COSV100594157; called by muse, mutect2
- SERPINA11 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100594159; called by muse, mutect2
- SGCD | c.135A>G p.I45M (on ENST00000435422 / NM_001128209.2; = p.I46M on NM_000337.5) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.247); catalogued as COSV100548300; called by muse, mutect2, varscan2
- SH2D5 | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100903892, COSV66706982; called by muse, mutect2, varscan2
- SHOC1 | c.3943C>G p.Q1315E | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597976; called by muse, mutect2
- SIRPG | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99403298; called by muse, varscan2
- SIRT3 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV101236028; called by muse, mutect2, varscan2
- SKIDA1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283921743, COSV101481336; called by muse, mutect2, varscan2
- SLAMF8 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99223088; called by muse, mutect2, varscan2
- SLC34A1 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100184090; called by muse, mutect2, varscan2
- SLC4A10 | c.1654G>T p.G552W (on ENST00000446997 / NM_001354461.2; = p.G522W on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771511, COSV99765436; called by muse, mutect2, varscan2
- SLC5A1 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56683463; called by mutect2, varscan2
- SLC9A2 | c.1066T>G p.Y356D | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.816); catalogued as COSV99296692; called by muse, mutect2, varscan2
- SLITRK6 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs925317873, COSV101233283; called by muse, mutect2
- SMG7 | c.2552C>G p.P851R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV100750149, COSV100750540; called by muse, mutect2
- SNRNP200 | c.3938G>C p.R1313T | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100108005; called by muse, mutect2
- SNRPN | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100578548; called by muse, mutect2, varscan2
- SNX27 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 17/130 reads (13%) | catalogued as COSV100919117; called by muse, mutect2, varscan2
- SOS2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99366689; called by muse, mutect2, varscan2
- SOX30 | c.1830C>A p.F610L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53937351, COSV99398723; called by muse, mutect2, varscan2
- SOX30 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as COSV53936356, COSV99398724; called by muse, mutect2, varscan2
- SPEM2 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as COSV100424464; called by muse, mutect2, varscan2
- SS18L1 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV100065289; called by muse, mutect2
- ST8SIA3 | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | PolyPhen benign (0.03); catalogued as COSV100129662; called by muse, mutect2
- STAB2 | c.4547C>A p.P1516Q | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141419387, COSV66345596; called by muse, mutect2, varscan2
- SYT8 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425606; called by muse, mutect2
- SYT8 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425607; called by muse, mutect2
- TAB3 | c.1982C>A p.A661D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV99916703; called by muse, mutect2
- TAOK1 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99914620; called by muse, mutect2, varscan2
- TCF4 | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as rs1324647610, COSV100610749; called by muse, mutect2, varscan2
- TEX14 | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs1454372652, COSV99543337; called by muse, mutect2, varscan2
- TGFBR2 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99847893; called by muse, mutect2, varscan2
- TGFBR2 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV99847899; called by muse, mutect2, varscan2
- THSD7A | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV101448866; called by muse, mutect2, varscan2
- TLL1 | c.837G>T p.M279I | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV99288832; called by muse, mutect2
- TLL1 | c.2776G>T p.G926C | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288836; called by muse, mutect2
- TMEFF2 | c.154A>C p.T52P | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); catalogued as COSV99772274; called by muse, mutect2, varscan2
- TMEM196 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV68257314; called by muse, mutect2, varscan2
- TMEM200A | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV51648975, COSV99759901; called by mutect2, varscan2
- TMEM260 | c.946A>G p.R316G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV99840608; called by muse, mutect2, varscan2
- TMEM68 | c.562A>G p.R188G | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV100588239; called by muse, mutect2
- TNN | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99512808; called by muse, mutect2, varscan2
- TNN | c.2110G>T p.A704S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99512810; called by muse, mutect2, varscan2
- TRIM33 | c.2534T>C p.M845T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1012256723, COSV100635679; called by muse, mutect2
- TRMT44 | c.1654G>C p.G552R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as COSV101077827; called by muse, mutect2, varscan2
- TRPC4 | c.1211G>C p.W404S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV100156835, COSV100157715; called by muse, mutect2, varscan2
- TRPC4AP | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99328832; called by muse, mutect2, varscan2
- TRPM8 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV100224454; called by muse, mutect2, varscan2
- TSPAN14 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100540405; called by muse, mutect2, varscan2
- TSPAN17 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.943); catalogued as COSV100024857; called by muse, mutect2, varscan2
- TTC13 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV100792997; called by muse, mutect2, varscan2
- TTC27 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100513487; called by muse, mutect2
- TTC3 | c.6037C>G p.P2013A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.046); catalogued as rs751950487; called by muse, mutect2
- TTN | c.30853C>T p.P10285S (on ENST00000591111; = p.P9358S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/333 reads (13%) | PolyPhen benign (0.003); catalogued as COSV100626674; called by muse, mutect2, varscan2
- TUT4 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99932739; called by muse, mutect2, varscan2
- UGT2B11 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101485288; called by muse, mutect2, varscan2
- USH2A | c.5065G>T p.E1689* | Nonsense Mutation (SNP) | VAF 44/183 reads (24%) | catalogued as COSV100241255; called by muse, mutect2, varscan2
- USP7 | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100784378; called by muse, mutect2, varscan2
- VAV3 | c.2311C>A p.H771N | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100580301; called by muse, mutect2
- VCAN | c.4432G>T p.E1478* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV54104629, COSV99427071; called by muse, mutect2, varscan2
- VEGFC | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs1389815142, COSV99710249; called by muse, mutect2, varscan2
- VNN1 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100907821; called by muse, mutect2
- VWA3B | c.733del p.D245Mfs*34 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | catalogued as rs1423955283; called by mutect2, pindel, varscan2
- XIRP2 | c.7486T>A p.S2496T (on ENST00000628543; = p.S2671T on NM_152381.6) | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99746611; called by muse, mutect2
- ZAN | c.2969C>A p.P990H | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100770224; called by muse, mutect2, varscan2
- ZBTB47 | c.1890G>C p.K630N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99234396; called by muse, mutect2, varscan2
- ZEB2 | c.1678C>G p.R560G | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.241); catalogued as COSV100356718, COSV57953987; called by muse, mutect2
- ZFHX3 | c.3065G>C p.G1022A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51713293, COSV99214361; called by muse, mutect2
- ZFHX4 | c.7772G>T p.S2591I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV99266695; called by mutect2, varscan2
- ZMIZ2 | c.946A>T p.M316L | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99537136; called by muse, mutect2, varscan2
- ZNF365 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101237983; called by muse, mutect2, varscan2
- ZNF385D | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55756041, COSV99876109; called by muse, mutect2, varscan2
- ZNF479 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100483007; called by muse, mutect2, varscan2
- ZNF479 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs1554400213, COSV100482446, COSV58643443; called by muse, mutect2, varscan2
- ZNF536 | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV62822880, COSV62827934; called by muse, mutect2, varscan2
- ZNF536 | c.3099C>A p.N1033K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV100835752; called by muse, mutect2, varscan2
- ZNF543 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386902; called by muse, mutect2, varscan2
- ZNF554 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100421300; called by muse, mutect2, varscan2
- ZNF616 | c.863A>C p.Q288P | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100348555; called by muse, mutect2
- ZNF674 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV101345057; called by muse, mutect2
- ZNF875 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100183532; called by muse, mutect2, varscan2
- ZSCAN10 | c.1474G>T p.E492* (on ENST00000252463; = p.E547* on NM_032805.3) | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99373807, COSV99374293; called by muse, mutect2, varscan2
- ZXDA | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100699460; called by muse, mutect2
- ZXDC | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100306605, COSV60445914; called by muse, mutect2, varscan2
- ALAS2 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CCL16 | c.362G>T p.*121Lext*1 | Nonstop Mutation (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- COLEC11 | c.392A>C p.Q131P | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CRPPA | c.1047del p.E350Kfs*6 (on ENST00000407010 / NM_001368197.1; = p.E300Kfs*6 on NM_001101417.4) | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- DCHS2 | n.2654A>G | Splice Region (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- DNAH5 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.102); called by muse, mutect2
- DNAI2 | c.1781A>G p.E594G | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.435); called by muse, mutect2
- FAM124A | c.1001G>T p.G334V (on ENST00000322475 / NM_001242312.2; = p.G370V on NM_145019.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2
- FCGBP | c.7880C>T p.S2627F | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); called by muse, mutect2
- HEPH | c.3203A>G p.H1068R (on ENST00000343002; = p.H801R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- HUWE1 | c.12868C>A p.Q4290K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- MCC | c.1066del p.V356Yfs*48 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- MYO9B | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.475); called by muse, mutect2
- PIGT | c.245dup p.R83Tfs*40 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, varscan2
- PIGT | c.246delinsTC p.R83Pfs*40 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | called by mutect2*, pindel, varscan2*
- PLCE1 | c.4338del p.M1447Cfs*10 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- PROM1 | c.2267G>A p.W756* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- RAG1 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TMEM33 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF527 | c.840dup p.D281* | Frame Shift Ins (INS) | VAF 37/270 reads (14%) | called by mutect2, pindel, varscan2
- ABL2 | c.2310C>T p.A770= (on ENST00000502732 / NM_007314.4; = p.A755= on NM_005158.5) | Silent (SNP) | VAF 39/234 reads (17%) | catalogued as rs1557906250, COSV100772932; called by muse, mutect2, varscan2
- ACE2 | c.2082C>A p.I694= | Silent (SNP) | VAF 16/330 reads (5%) | catalogued as COSV53027164, COSV99382677, COSV99383066; called by muse, mutect2
- ACTL6B | c.1215G>A p.Q405= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99355719; called by muse, mutect2
- ADCY8 | c.2314C>A p.R772= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs749479126, COSV53898899, COSV99653918; called by muse, mutect2
- ADGRA2 | c.2028C>T p.T676= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV59444437; called by muse, varscan2
- ANK1 | c.2052A>G p.A684= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs922979408, COSV99226588; called by muse, mutect2
- BTNL9 | c.1497C>T p.P499= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100576226; called by muse, mutect2, varscan2
- C9 | c.1107G>T p.R369= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV99662461; called by muse, mutect2, varscan2
- C9orf131 | c.714G>A p.R238= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as rs776011520, COSV100398250; called by muse, mutect2, varscan2
- CAPN13 | c.924G>T p.R308= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99700967; called by muse, mutect2, varscan2
- CDC42BPG | c.2938C>T p.L980= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100712143; called by muse, mutect2, varscan2
- CDH18 | c.309T>A p.I103= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV99937751; called by muse, mutect2
- CFAP47 | c.552C>A p.P184= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV52887022; called by muse, mutect2, varscan2
- CLDND2 | c.75C>G p.S25= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99389968; called by muse, mutect2, varscan2
- COL15A1 | c.3048A>G p.L1016= | Silent (SNP) | VAF 75/336 reads (22%) | catalogued as rs201121426, COSV100897933; called by muse, mutect2, varscan2
- COL6A2 | c.333G>T p.P111= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100154120; called by muse, mutect2, varscan2
- CRACR2A | c.147A>T p.L49= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99364995, COSV99365421; called by muse, mutect2
- CRISPLD1 | c.94T>C p.L32= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as COSV100082366; called by muse, mutect2, varscan2
- CYP11B1 | c.822C>A p.I274= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99455608; called by muse, mutect2, varscan2
- DAB2 | c.1281C>T p.S427= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV100298265; called by muse, mutect2, varscan2
- DDX27 | c.1464G>T p.L488= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100873501; called by muse, mutect2
- DGKB | c.801C>A p.G267= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs748583715, COSV99342797; called by muse, mutect2
- EPM2AIP1 | c.1134T>G p.L378= | Silent (SNP) | VAF 56/408 reads (14%) | catalogued as COSV99212646; called by muse, mutect2, varscan2
- FAM153A | c.438G>T p.L146= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100647115; called by muse, mutect2
- FAM153B | c.669G>T p.L223= (on ENST00000253490; = p.L146= on NM_001265615.1) | Silent (SNP) | VAF 13/310 reads (4%) | catalogued as COSV99499116; called by muse, mutect2
- FAT2 | c.2613C>T p.L871= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99943932; called by muse, mutect2, varscan2
- FGF10 | c.405C>T p.N135= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1385271154, COSV99240918; called by muse, mutect2, varscan2
- FGFR4 | c.492G>A p.A164= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs139194967, COSV52807045; called by muse, mutect2, varscan2
- FLG | c.10656T>A p.S3552= | Silent (SNP) | VAF 174/621 reads (28%) | catalogued as COSV100912025; called by muse, mutect2, varscan2
- FST | c.609G>A p.E203= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs745323166, COSV99887414; called by muse, mutect2, varscan2
- GAD2 | c.216C>A p.A72= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99393915; called by muse, mutect2, varscan2
- GAL3ST4 | c.759C>A p.T253= | Silent (SNP) | VAF 24/288 reads (8%) | catalogued as COSV100385618; called by muse, mutect2
- GPR31 | c.81G>A p.L27= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100834168; called by muse, mutect2, varscan2
- GRIA2 | c.312C>T p.C104= | Silent (SNP) | VAF 23/229 reads (10%) | catalogued as rs767578632, COSV52408659; called by muse, mutect2
- GUCY2F | c.1891C>T p.L631= | Silent (SNP) | VAF 11/200 reads (6%) | catalogued as COSV99485541; called by muse, mutect2
- H4C4 | c.150C>T p.L50= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs760487699, COSV100534491; called by muse, mutect2, varscan2
- HTR2C | c.1257C>T p.T419= | Silent (SNP) | VAF 13/270 reads (5%) | catalogued as COSV99350663; called by muse, mutect2
- IGHE | c.180C>A p.L60= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- IL31RA | c.1905G>A p.L635= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs1032962839, COSV100732862; called by muse, mutect2, varscan2
- ITGB1 | c.102A>T p.S34= | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as rs898998183, COSV100171949; called by muse, mutect2
- ITGB6 | c.570A>C p.P190= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV51792245; called by muse, mutect2
- KCNC2 | c.6C>A p.G2= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs199730100, COSV100129681; called by muse, mutect2, varscan2
- LIN7B | c.291C>T p.P97= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99674576; called by muse, mutect2, varscan2
- LRRC2 | c.594T>C p.S198= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV99947615; called by muse, mutect2, varscan2
- LRRN2 | c.984C>G p.P328= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100912934; called by muse, mutect2, varscan2
- MBD4 | c.27G>C p.L9= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99959754; called by muse, mutect2
- MBL2 | c.321G>T p.L107= | Silent (SNP) | VAF 28/177 reads (16%) | catalogued as COSV100906394, COSV64759606; called by muse, mutect2, varscan2
- MGMT | c.474G>T p.A158= (on ENST00000306010; = p.A127= on NM_002412.5) | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV60022206; called by muse, mutect2, varscan2
- MUC16 | c.38373G>C p.L12791= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as COSV101201223; called by muse, mutect2
- MUC17 | c.10041C>T p.F3347= | Silent (SNP) | VAF 123/745 reads (17%) | catalogued as COSV100074813; called by muse, mutect2, varscan2
- MYH13 | c.1725T>A p.A575= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV99355179; called by muse, mutect2, varscan2
- MYO1A | c.912G>A p.E304= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100271204; called by muse, mutect2, varscan2
- MYOG | c.378C>A p.I126= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV99614043; called by muse, mutect2, varscan2
- MYOM2 | c.2511G>T p.V837= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100038229; called by muse, mutect2
- NAV3 | c.3156C>A p.P1052= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as COSV57105275, COSV99894731; called by muse, mutect2, varscan2
- NLGN4X | c.1002C>A p.A334= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV52023556; called by muse, mutect2
- NLRP5 | c.1974C>G p.P658= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV101173857; called by muse, mutect2, varscan2
- NRXN2 | c.1206C>A p.I402= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV99635503; called by muse, mutect2, varscan2
- NUCB1 | c.36G>C p.L12= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99618107; called by muse, mutect2, varscan2
- OBSCN | c.12504G>T p.A4168= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV52827615, COSV52840811; called by muse, mutect2, varscan2
- OR14A16 | c.432T>A p.T144= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV100713857; called by muse, mutect2, varscan2
- OR2L3 | c.426G>A p.L142= | Silent (SNP) | VAF 40/287 reads (14%) | catalogued as rs756226601, COSV100742037; called by muse, varscan2
- OR4P4 | c.339C>T p.L113= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV100111829; called by muse, mutect2, varscan2
- OR51I1 | c.21C>T p.T7= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV100971948; called by muse, mutect2
- ORC4 | c.687A>T p.I229= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99932450; called by muse, mutect2
- PCDHA4 | c.1278C>G p.T426= | Silent (SNP) | VAF 39/233 reads (17%) | catalogued as COSV100793699; called by muse, mutect2, varscan2
- PCDHA4 | c.1854G>T p.A618= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV63541741; called by muse, mutect2, varscan2
- PCDHB2 | c.1824G>T p.L608= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as COSV99166386; called by muse, mutect2, varscan2
- PCDHGA5 | c.2139G>T p.V713= | Silent (SNP) | VAF 42/368 reads (11%) | catalogued as rs575828819, COSV99545416; called by muse, mutect2, varscan2
- POLQ | c.7353A>T p.P2451= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV99952252, COSV99952818; called by muse, mutect2, varscan2
- POLQ | c.1617A>T p.I539= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV99952821; called by muse, varscan2
- PRUNE2 | c.6687A>G p.E2229= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100945052; called by muse, mutect2
- PTCHD3 | c.153G>A p.P51= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as rs1386975242, COSV71256764, COSV71257170; called by muse, mutect2
- PWWP3B | c.1575G>A p.P525= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs182305110, COSV100531558, COSV61799543, COSV61801241; called by mutect2, varscan2
- QRFPR | c.660C>T p.V220= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV100543931; called by muse, mutect2
- RBBP5 | c.567C>T p.F189= | Silent (SNP) | VAF 27/371 reads (7%) | catalogued as COSV99196884; called by muse, mutect2
- RYR2 | c.10372C>A p.R3458= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV63692125, COSV63716462; called by muse, mutect2
- SCAF11 | c.4332G>T p.R1444= | Silent (SNP) | VAF 43/222 reads (19%) | catalogued as COSV101014603; called by muse, mutect2, varscan2
- SCAMP3 | c.216G>C p.S72= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV100226894, COSV56945431; called by muse, mutect2
- SDCCAG8 | c.1278A>T p.T426= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100654539; called by muse, mutect2, varscan2
- SEC16B | c.2007A>G p.L669= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV100381878; called by muse, mutect2
- SERINC5 | c.702A>T p.G234= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV101549126; called by muse, mutect2
- SERPINA3 | c.618C>A p.V206= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as COSV101261796; called by muse, mutect2
- SLC35A5 | c.942A>G p.A314= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV99656904; called by muse, mutect2, varscan2
- SLC35F2 | c.504G>T p.V168= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99758845; called by muse, mutect2, varscan2
- SLC4A10 | c.1338C>T p.S446= (on ENST00000446997 / NM_001354461.2; = p.S416= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV99765431; called by muse, mutect2
- SLC8A1 | c.2010G>T p.P670= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs137879982, COSV100245989; called by muse, mutect2, varscan2
- SLIT3 | c.3858C>A p.T1286= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100269444; called by mutect2, varscan2
- ST18 | c.2598A>T p.L866= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV99390837; called by muse, mutect2
- TLR4 | c.1515G>A p.Q505= (on ENST00000355622 / NM_138554.5; = p.Q465= on NM_003266.4) | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV100842839, COSV62924189; called by muse, mutect2, varscan2
- TMCO3 | c.1212G>T p.R404= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as COSV100952417; called by muse, mutect2, varscan2
- TRAV20 | c.315C>A p.A105= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- TRAV26-1 | c.279C>A p.P93= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- TRHR | c.624C>A p.T208= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV100305061; called by muse, mutect2, varscan2
- TRPC4 | c.1704G>A p.L568= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100157036; called by muse, mutect2
- TRPC4AP | c.1161C>T p.Y387= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99328827; called by muse, mutect2, varscan2
- TRPC7 | c.309G>A p.L103= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs369841454; called by muse, mutect2, varscan2
- TRPM5 | c.549C>T p.F183= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV50166939, COSV99329518; called by muse, mutect2
- UROS | c.186C>T p.T62= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100908900; called by muse, mutect2, varscan2
- VWA3B | c.2964A>T p.L988= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as COSV101346133; called by muse, mutect2, varscan2
- WDR91 | c.1416G>T p.V472= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100615814; called by muse, mutect2, varscan2
- ZNF382 | c.831C>G p.L277= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as COSV53093132, COSV99498054; called by muse, mutect2, varscan2
- ZNF624 | c.384G>A p.E128= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100257410; called by muse, mutect2
- AC024940.1 | n.3580T>A | RNA (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- ACAA2 | chr18:49814227 G>C | 5'Flank (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668165 A>C | 5'Flank (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849596 C>A | 5'Flank (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- AP2A2 | c.*700G>T | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as rs934120008, COSV100173267; called by muse, mutect2, varscan2
- COL11A1 | c.897+283A>T | Intron (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100617895; called by muse, mutect2
- DNAH14 | c.1032+127A>G | Intron (SNP) | VAF 27/107 reads (25%) | catalogued as rs1407499455, COSV100835968; called by muse, mutect2, varscan2
- DPP6 | c.627+20942del | Intron (DEL) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- FBLN1 | c.1698-11373G>C | Intron (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99411316; called by muse, mutect2
- GRM7 | c.2698+6063C>T | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100738169; called by muse, mutect2
- IFRD2 | c.-74C>A | 5'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100269788, COSV57116061; called by muse, mutect2
- IL5RA | c.994+1973T>A | Intron (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99843239; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847753 G>T | 5'Flank (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- MAGEA5 | n.167C>T | RNA (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- MIR492 | n.19C>A | RNA (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- NBPF7 | n.404C>A | RNA (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- OR4K17 | c.-27C>G | 5'UTR (SNP) | VAF 23/189 reads (12%) | catalogued as COSV59647460, COSV59648966; called by muse, mutect2, varscan2
- SP110 | c.1815+356G>T | Intron (SNP) | VAF 8/121 reads (7%) | catalogued as COSV99283728; called by muse, mutect2
- SV2C | c.581-21262C>G | Intron (SNP) | VAF 56/349 reads (16%) | catalogued as rs753396970, COSV59213056; called by muse, mutect2, varscan2
- TTN | c.10361-5140A>T | Intron (SNP) | VAF 24/169 reads (14%) | catalogued as COSV100626676; called by muse, mutect2, varscan2
